Gene-level copy-number profile of tumor specimen REBC-AF5C-TTP1 from REBC case REBC-AF5C, project REBC-THYR (Comprehensive genomic characterization of radiation-related papillary thyroid cancer in the Ukraine). Sex at birth: female; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland.
Specimen REBC-AF5C-TTP1: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 8064cc16-5029-4629-a4ab-df03ebf5da97.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator REBC-AF5C-NB1-SC208233 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,225 have no estimate.
https://portal.gdc.cancer.gov/files/34617c60-0d56-4622-a6c3-f99d4ce80687

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 2,641; copy number 2: 55,488; copy number 3: 265.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:90,261,414–90,261,708, 1 gene: HSPE1P19.
- chr6:60,281,444–60,546,660, 1 gene: AC244258.1.
- chr7:62,275,361–62,275,678, 1 gene: AC128676.1.
- chr21:12,999,676–13,016,692, 1 gene: AP001464.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 2,623. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
